Somatic mutation profile of tumor specimen TCGA-TS-A7OZ-01A (aliquot TCGA-TS-A7OZ-01A-21D-A39R-32) from TCGA case TCGA-TS-A7OZ, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 67.7 years (24,745 days).
Specimen TCGA-TS-A7OZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d74d21bf-697e-45d6-8d7d-08a3ad0d142f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TS-A7OZ-10B (Blood Derived Normal), aliquot TCGA-TS-A7OZ-10B-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7fab5c3b-7031-4aa2-8f6d-cbd77bbd8dbe

The open-access MAF lists 50 somatic variants for this specimen: 37 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 27, Silent 13, Nonsense Mutation 5, In Frame Del 2, Splice Region 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EXT2 | c.1173G>A p.Q391= (on ENST00000343631; = p.Q424= on NM_000401.3) | Splice Region (SNP) | VAF 17/52 reads (33%) | catalogued as rs1457613214, COSV59153236; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ARHGEF18 | c.1730G>A p.R577Q (on ENST00000359920 / NM_001130955.2; = p.R473Q on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs754731608; called by muse, mutect2, varscan2
- BAP1 | c.1951_1953del p.K651del | In Frame Del (DEL) | VAF 14/81 reads (17%) | catalogued as rs1226165465; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- BIRC6 | c.1923A>T p.K641N | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV70200954; called by muse, mutect2, varscan2
- COA5 | c.156C>G p.Y52* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as COSV60831074; called by muse, varscan2
- CYP2S1 | c.649G>A p.G217S | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.28); catalogued as rs1179158669; called by muse, mutect2, varscan2
- FBN1 | c.7041G>C p.M2347I | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.844); catalogued as COSV57324623; called by muse, mutect2, varscan2
- FCRL3 | c.1852G>T p.E618* | Nonsense Mutation (SNP) | VAF 10/79 reads (13%) | catalogued as COSV63839619; called by muse, mutect2, varscan2
- FRMD1 | c.49C>A p.P17T | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.486); catalogued as rs1253234518; called by muse, mutect2, varscan2
- GSN | c.2329A>G p.M777V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1460889014; called by muse, mutect2
- NF2 | c.576C>G p.Y192* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as CM994608, COSV100097796, COSV58520186, COSV58532890; called by muse, mutect2, varscan2
- PCDH10 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 12/48 reads (25%) | catalogued as COSV52089528; called by muse, mutect2, varscan2
- SLC6A5 | c.1395G>A p.T465= | Splice Region (SNP) | VAF 10/37 reads (27%) | catalogued as rs773583338, COSV54226416; called by muse, mutect2
- TACC2 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV57778125; called by muse, mutect2, varscan2
- ADAM9 | c.943A>G p.M315V | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRL4 | c.1316T>A p.L439Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AKAP8 | c.752C>G p.S251C | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ARID5B | c.2718_2726del p.D907_S909del | In Frame Del (DEL) | VAF 22/72 reads (31%) | called by mutect2, pindel, varscan2
- ARIH1 | c.1163A>G p.N388S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.336); called by muse, varscan2
- BIRC6 | c.3218A>T p.H1073L | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BMP15 | c.994C>A p.L332I | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- BTN1A1 | c.1160T>A p.M387K | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- CRACD | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CRIM1 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- DDX17 | c.1768G>C p.G590R | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- FCRL3 | c.1853A>T p.E618V | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2
- GNPNAT1 | c.171G>C p.L57F | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAN1C1 | c.480G>C p.R160S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- NLRP9 | c.1240G>T p.D414Y | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NPHP3 | c.935C>A p.P312H | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEKHB1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- RNF185 | c.280A>T p.R94W | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- RPRD2 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 34/131 reads (26%) | called by muse, mutect2, varscan2
- RTKN | c.1687G>A p.V563M (on ENST00000272430 / NM_001015055.2; = p.V550M on NM_033046.2) | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TCTE3 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRAIP | c.796-21_811del p.X266_splice | Splice Site (DEL) | VAF 13/79 reads (16%) | called by mutect2, pindel
- TRMT61B | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C16orf90 | c.513C>A p.T171= (on ENST00000399645 / NM_001353385.2; = p.T162= on NM_001080524.2) | Silent (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- CD37 | c.624G>A p.A208= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV60544308; called by muse, mutect2, varscan2
- CKAP2L | c.1965A>G p.E655= | Silent (SNP) | VAF 24/124 reads (19%) | called by muse, mutect2, varscan2
- EME2 | c.987C>T p.S329= | Silent (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- INTS5 | c.2316G>A p.V772= | Silent (SNP) | VAF 22/70 reads (31%) | called by muse, mutect2, varscan2
- NCDN | c.618C>G p.A206= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV57849383, COSV57849564; called by muse, mutect2, varscan2
- NR2C1 | c.594C>G p.S198= | Silent (SNP) | VAF 24/95 reads (25%) | called by muse, mutect2, varscan2
- OR8K5 | c.117G>C p.V39= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as rs148921775; called by muse, mutect2, varscan2
- PCDH17 | c.1152C>T p.N384= | Silent (SNP) | VAF 18/82 reads (22%) | catalogued as rs760178198, COSV64973447; called by muse, mutect2, varscan2
- PKN2 | c.15C>T p.P5= | Silent (SNP) | VAF 3/8 reads (38%) | called by muse, mutect2
- RPL7A | c.60G>A p.K20= | Silent (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- RXRG | c.1029C>G p.V343= | Silent (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2, varscan2
- SOGA3 | c.1239C>T p.L413= | Silent (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
